Surgical pathology report (de-identified scan), TCGA case TCGA-2J-AAB8, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Mayo Clinic, specimen TCGA-2J-AAB8-01A (Primary Tumor).

[page 1 of 3]
Surgery date: Surgical Pathology

ICD0-3

Adenocarcinoma, ductal NOS
850013

DIAGNOSIS:

A. Liver, right lobe, biopsy: Bile duct hamartoma. Negative for malignancy.

Site: Pancreas head
C25.0

7/5/5/14

B. Lymph nodes, hepatic hilar, biopsy: Multiple (2) lymph nodes are negative for tumor.

C. Common hepatic duct, margin, excision: Negative for malignancy.

D. Pancreas, neck margin, excision: Negative for malignancy.

E. Head of pancreas, common bile duct, duodenum, jejunum, and gallbladder; Whipple resection: Invasive moderately differentiated grade 3 (of 4) ductal adenocarcinoma is identified forming a solid 3.5 x 2.8 x 2.4 cm mass located in the pancreatic head. The tumor extends beyond the pancreas to involve pancreatic soft tissue and distal common bile duct. Angiolymphatic invasion is identified. Perineural invasion is present. Tumor necrosis is absent. The portal vein groove margin is focally positive for invasive carcinoma. The portion of superior mesenteric vein is negative for tumor. The adjacent non-neoplastic pancreatic parenchyma shows chronic pancreatitis. Multiple (3 of 25) regional lymph nodes are positive for metastatic adenocarcinoma.

With available surgical material, [AJCC pT3N1] (7th edition, 2010).

Frozen section histologic interpretation of right lobe of liver performed by:

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "lesion, right lobe liver biopsy" is a 1.2 x 0.6 x 0.6 cm fragment of liver with a 0.4 x 0.4 x 0.3 cm tan firm nodule. All submitted. Grossed by

B. Received fresh labeled "hepatic hilar lymph nodes" is a 2.1 x 1.6 x 0.8 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted. Grossed by

[page 2 of 3]
C. Received fresh labeled "common hepatic duct margin" is a 0.8 x 0.7 x 0.3 cm portion of tan tubular tissue without orientation. Margin submitted. Grossed by

D. Received fresh labeled "pancreatic neck margin" is a 3.1 x 1.1 x 0.4 cm portion of tan lobulated pancreas without orientation. Margin submitted. Grossed by

E. Received fresh labeled "head of pancreas, portion of common bilateral duct, portion of jejunum, portion of supramesenteric vein, gallbladder" is a Whipple specimen consisting of 30.3 cm in length portion of duodenum, 7.0 x 6.3 x 2.8 cm portion of pancreas, a 10.9 x 4.7 x 3.0 cm gallbladder and a 1.4 x 0.4 x 0.3 cm portion of superior mesenteric vein. The pancreatic uncinate margin is inked yellow and shaved. The portal vein groove is inked black and submitted perpendicularly. There is a 3.5 x 2.8 x 2.4 cm infiltrative mass within the head of the pancreas, less than 0.1 cm from the portal vein groove margin. The mass extends to peripancreatic soft tissue. A stent is present within the common bile duct measuring 9.5 cm. The gallbladder contains no choleliths. Peripancreatic lymph nodes and periduodenal lymph nodes are identified. Representative sections are submitted. Grossed by

BLOCK SUMMARY:

Part A: Lesion right lobe liver biopsy

1 Rt lobe liver

Part B: Hepatic hilar lymph nodes

1 Hepatic hilar LN2 (B1)

2 Hepatic hilar LN1 (B2)

Part C: Common hepatic duct margin

1 Common hepatic duct margin

Part D: Pancreatic neck margin

1 Pancreatic neck margin 1

2 Pancreatic neck margin 2

Part E: Head of pancreas, portion common bile duct, duodenum, portion jejunum, portion supramesenteric vein, gallbladder

1 Uncinate margin 1

2 Uncinate margin 2

3 Uncinate margin 3

4 Uncinate margin 3

5 Portal vein groove margin

6 Mass w/ sup mesenteric vein

7 Mass w/ common bile duct

8 Pancreas mass 1

[page 3 of 3]
- 9 Ampulla
- 10 Pancreas mass 2
- 11 Peri pancreatic LN5(E1)
- 12 Peri pancreatic tissue(E2)
- 13 Peri pancreatic LN5(E3)
- 14 Peri pancreatic LN1(E4)
- 15 Pericholedochal LN1(E5)
- 16 Gallbladder
- 17 Peri pancreatic LN4(E6)
- 18 Peri pancreatic LN5(E7)
- 19 Peri pancreatic LN2(E8)
- 20 Peri pancreatic LN4(E9)
- 21 Peri pancreatic LN4(E10)
- 22 Peri pancreatic LN1(E11)
- 23 Peri pancreatic LN1(E12)
- 24 Peri pancreatic LN2(E13)
- 25 Peri pancreatic LN3(E14)
- 26 Peri pancreatic LN5(E15)

Source: NCI Genomic Data Commons file 1b46c7d0-0a4a-48b7-9da4-f2a5df58d91f (TCGA-2J-AAB8.831D9770-7EA3-49F7-9984-27930F239A34.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).